CCDI case PBBRNV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Retroperitoneum and peritoneum.
https://portal.gdc.cancer.gov/cases/3fd45a2e-e313-4667-aea0-5d8cca83e9cb

Demographics
Sex at birth: female.

Diagnoses (1)
1. Aggressive fibromatosis: ICD-O-3 morphology code: 8821/1; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 16.2 years (5,908 days).

Biospecimens (3 samples)
- Sample 0DFJJ0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFJKD: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFJMY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
